Somatic mutation profile of tumor specimen C3N-02997-01 (aliquot CPT0187880025) from CPTAC case C3N-02997, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 73.5 years (26,837 days).
Specimen C3N-02997-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55db74aa-c900-435c-abdd-776f96ac9f17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02997-31 (Blood Derived Normal), aliquot CPT0187920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc04600c-11b5-4d05-adc8-03bbd0a2b739

The open-access MAF lists 81 somatic variants for this specimen: 56 protein-altering or splice-affecting, 18 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 18, Nonsense Mutation 5, Frame Shift Ins 3, 3'UTR 2, Frame Shift Del 2, RNA 2, In Frame Del 1, 3'Flank 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 285/1110 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DCC | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 125/545 reads (23%) | catalogued as rs754914260, CM145915, COSV100502237, COSV59130602; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 116/581 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 137/536 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- ADAMTS17 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 119/822 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs142108260; called by muse, mutect2, varscan2
- ADAMTS2 | c.3544C>T p.R1182* | Nonsense Mutation (SNP) | VAF 136/815 reads (17%) | catalogued as rs367553801; ClinVar: uncertain significance; called by muse, mutect2
- ARHGAP31 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 123/634 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765209939, COSV51794256; called by muse, mutect2, varscan2
- CACNA1B | c.6553G>A p.G2185S | Missense Mutation (SNP) | VAF 170/938 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.708); catalogued as rs538992240, COSV53111911; called by muse, mutect2, varscan2
- CSH1 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 172/889 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs147130406; called by muse, mutect2, varscan2
- CYP26A1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1197501700; called by muse, varscan2
- DCLRE1A | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 119/568 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767319245; called by muse, mutect2, varscan2
- EGR3 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 207/859 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1259984282, COSV100416239; called by muse, mutect2, varscan2
- ERBB4 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 146/822 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs138433638, COSV53504288; called by muse, mutect2, varscan2
- ITIH5 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 128/674 reads (19%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.583); catalogued as rs1356540059; called by muse, mutect2, varscan2
- KMT2A | c.11522G>A p.R3841Q | Missense Mutation (SNP) | VAF 66/493 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63285492; called by muse, mutect2, varscan2
- LRP2 | c.12187C>T p.R4063* | Nonsense Mutation (SNP) | VAF 65/540 reads (12%) | catalogued as rs762645702, COSV55561498; called by muse, mutect2, varscan2
- NSMCE3 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 208/1112 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.43); catalogued as COSV99722365; called by muse, mutect2, varscan2
- PCSK4 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 118/566 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1429456314; called by muse, mutect2, varscan2
- PNMA8A | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 496/966 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs547519581, COSV58136662; called by muse, mutect2, varscan2
- ROBO2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 147/899 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as rs745544902, COSV59911587; called by muse, mutect2, varscan2
- RUNX1 | c.982dup p.Y328Lfs*245 (on ENST00000344691 / NM_001001890.3; = p.Y355Lfs*245 on NM_001754.5) | Frame Shift Ins (INS) | VAF 215/1254 reads (17%) | catalogued as COSV55868527; called by mutect2, pindel, varscan2
- SDR16C5 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 209/640 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749076138; called by muse, mutect2, varscan2
- SERPINA6 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 222/1066 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.208); catalogued as COSV58584388; called by muse, mutect2, varscan2
- SHROOM2 | c.3299C>T p.A1100V | Missense Mutation (SNP) | VAF 236/657 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs747687263, COSV66606247; called by muse, mutect2, varscan2
- SLC25A27 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 113/741 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs771239382; called by muse, mutect2, varscan2
- SYDE1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 202/906 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1216431016; called by muse, mutect2, varscan2
- SYNDIG1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 199/1042 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as rs778443324, COSV100965292, COSV65237741; called by muse, mutect2, varscan2
- TRIM42 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 190/1062 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs777678502, COSV53880304, COSV53886166; called by muse, mutect2, varscan2
- TTN | c.13892C>G p.P4631R (on ENST00000591111; = p.P3704R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/853 reads (19%) | PolyPhen possibly damaging (0.771); catalogued as COSV100600556; called by muse, mutect2, varscan2
- WWC2 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 120/759 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101330845; called by muse, mutect2, varscan2
- ZNF592 | c.3329A>G p.N1110S | Missense Mutation (SNP) | VAF 262/846 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs750398742; called by muse, mutect2, varscan2
- ZNF852 | c.1591_1593del p.L531del | In Frame Del (DEL) | VAF 101/559 reads (18%) | catalogued as rs755518667; called by pindel, varscan2
- AHNAK2 | c.7448T>A p.F2483Y | Missense Mutation (SNP) | VAF 167/871 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ANK2 | c.7357_7360del p.D2453Lfs*7 | Frame Shift Del (DEL) | VAF 122/788 reads (15%) | called by mutect2, pindel, varscan2
- CCDC18 | c.2746G>C p.E916Q (on ENST00000343253 / NM_001306076.1; = p.E917Q on NM_206886.4) | Missense Mutation (SNP) | VAF 78/424 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CNN2 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 169/670 reads (25%) | called by muse, mutect2, varscan2
- EPS15L1 | c.1733A>C p.D578A | Missense Mutation (SNP) | VAF 59/791 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.118); called by muse, mutect2
- FYB1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 173/1193 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- HSPG2 | c.4720C>T p.P1574S | Missense Mutation (SNP) | VAF 83/593 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- IFI16 | c.1710A>C p.E570D (on ENST00000295809 / NM_001364867.2; = p.E514D on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/799 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KANSL1 | c.2253dup p.D752Rfs*29 | Frame Shift Ins (INS) | VAF 186/1203 reads (15%) | called by mutect2, pindel, varscan2
- OR5H6 | c.62A>T p.N21I (on ENST00000642105; = p.N5I on NM_001005479.2) | Missense Mutation (SNP) | VAF 96/596 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- P2RY13 | c.969dup p.F324Ifs*22 | Frame Shift Ins (INS) | VAF 129/757 reads (17%) | called by mutect2, pindel, varscan2
- PLEKHG4B | c.1291G>C p.E431Q (on ENST00000283426; = p.E787Q on NM_052909.5) | Missense Mutation (SNP) | VAF 146/790 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- POTEB3 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 26/939 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2
- REST | c.2525T>G p.L842* | Nonsense Mutation (SNP) | VAF 127/672 reads (19%) | called by muse, mutect2, varscan2
- SCRIB | c.3099G>T p.E1033D | Missense Mutation (SNP) | VAF 164/1302 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2009C>A p.A670E (on ENST00000540229 / NM_001371097.1; = p.A609E on NM_001009562.4) | Missense Mutation (SNP) | VAF 57/432 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SMARCA5 | c.148A>C p.S50R | Missense Mutation (SNP) | VAF 72/506 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by mutect2, varscan2
- SNTG2 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 105/615 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK11 | c.166_173del p.G56Lfs*104 | Frame Shift Del (DEL) | VAF 137/804 reads (17%) | called by mutect2, pindel, varscan2
- STK11IP | c.2828A>G p.E943G | Missense Mutation (SNP) | VAF 115/717 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TBC1D23 | c.1752G>T p.W584C (on ENST00000394144 / NM_001199198.3; = p.W569C on NM_018309.5) | Missense Mutation (SNP) | VAF 93/539 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRBV4-2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 89/859 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- TTN | c.84099C>A p.D28033E (on ENST00000591111; = p.D20609E on NM_003319.4) | Missense Mutation (SNP) | VAF 159/960 reads (17%) | PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UNC80 | c.7805T>G p.L2602W | Missense Mutation (SNP) | VAF 68/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADRA2B | c.249G>A p.T83= | Silent (SNP) | VAF 88/1194 reads (7%) | catalogued as rs879243154, COSV69788380; called by muse, mutect2
- ARIH1 | c.255C>T p.G85= | Silent (SNP) | VAF 60/1488 reads (4%) | catalogued as rs754910711, COSV65910196; called by muse, mutect2
- C17orf49 | c.48C>T p.G16= | Silent (SNP) | VAF 148/606 reads (24%) | called by muse, mutect2, varscan2
- CELA3A | c.591C>T p.T197= | Silent (SNP) | VAF 110/661 reads (17%) | catalogued as rs200714940; called by muse, mutect2, varscan2
- CSMD1 | c.8016C>T p.S2672= (on ENST00000520002; = p.S2671= on NM_033225.6) | Silent (SNP) | VAF 77/389 reads (20%) | catalogued as rs764119199, COSV100147704; called by muse, mutect2, varscan2
- E4F1 | c.1941T>A p.T647= | Silent (SNP) | VAF 58/990 reads (6%) | catalogued as COSV100065713; called by muse, mutect2
- EPS15L1 | c.1735C>T p.L579= | Silent (SNP) | VAF 59/790 reads (7%) | catalogued as rs761516124; called by muse, mutect2
- HSPA12B | c.108C>T p.C36= | Silent (SNP) | VAF 131/755 reads (17%) | catalogued as rs762188692; called by muse, mutect2, varscan2
- ILDR2 | c.1590C>T p.G530= | Silent (SNP) | VAF 243/1398 reads (17%) | catalogued as rs1231965694; called by muse, mutect2, varscan2
- KHDC3L | c.435G>A p.T145= | Silent (SNP) | VAF 226/1117 reads (20%) | catalogued as COSV64863674; called by muse, mutect2, varscan2
- KMT2D | c.7842G>A p.S2614= | Silent (SNP) | VAF 181/1050 reads (17%) | catalogued as COSV99986251; called by muse, mutect2, varscan2
- KRT73 | c.54C>T p.S18= | Silent (SNP) | VAF 201/905 reads (22%) | catalogued as rs74778340; called by muse, mutect2, varscan2
- LRIT1 | c.477C>T p.F159= | Silent (SNP) | VAF 180/976 reads (18%) | called by muse, mutect2, varscan2
- OTX1 | c.582G>A p.P194= | Silent (SNP) | VAF 229/1216 reads (19%) | called by muse, mutect2, varscan2
- RP1 | c.3360C>T p.F1120= | Silent (SNP) | VAF 102/538 reads (19%) | called by muse, varscan2
- SLCO5A1 | c.2499G>A p.A833= | Silent (SNP) | VAF 176/1090 reads (16%) | catalogued as COSV52661816, COSV99481199; called by muse, mutect2, varscan2
- SNAPC2 | c.48C>T p.G16= | Silent (SNP) | VAF 183/820 reads (22%) | catalogued as rs753989260; called by muse, mutect2, varscan2
- WDR90 | c.3300G>A p.P1100= | Silent (SNP) | VAF 162/844 reads (19%) | catalogued as rs375330337, COSV53473930; called by muse, mutect2, varscan2
- AMDHD2 | c.*1041G>A | 3'UTR (SNP) | VAF 154/855 reads (18%) | catalogued as rs1247076616; called by muse, mutect2, varscan2
- NAMPTP1 | n.1030G>A | RNA (SNP) | VAF 134/696 reads (19%) | called by muse, mutect2, varscan2
- STMP1 | chr7:135660438 C>G | 5'Flank (SNP) | VAF 37/301 reads (12%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75511056 C>T | 3'Flank (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- ZNF137P | n.1660C>G | RNA (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- ZNF688 | c.-618T>C | 5'UTR (SNP) | VAF 138/734 reads (19%) | catalogued as rs1189436571; called by muse, mutect2, varscan2
- ZNF717 | c.*38C>T | 3'UTR (SNP) | VAF 78/419 reads (19%) | called by muse, mutect2, varscan2
